Gene-level copy-number profile of tumor specimen TCGA-HC-8265-01A from TCGA case TCGA-HC-8265, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.8 years (24,382 days).
Specimen TCGA-HC-8265-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.1a1044d4-bb25-4312-a18d-0a471e7457d4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-8265-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7dc78e0b-4c57-4e48-94cd-db7e73fdf887

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,632; copy number 2: 49,627; copy number 3: 7,121; copy number 4: 375; copy number 5: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-8265-01A-11D-2259-01): tumor purity 0.5, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 60 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:163,323,962–163,520,539, 5 genes, copy number 5 (within-gene range 3–5): NPY1R, NPY5R, RPL35AP12, TKTL2, TMA16.
- chr4:163,529,771–163,530,697, 1 gene, copy number 5: AC093788.1.
- chr7:15,200,317–17,467,256, 34 genes, copy number 5 (within-gene range 2–5): AGMO, MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2, AC073333.1, TSPAN13, AGR2, AC073333.2, AGR3, RAD17P1, AC098592.2, AHR, AC098592.1, AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2.
- chr8:111,093,263–114,791,929, 20 genes, copy number 5 (within-gene range 3–5): LINC01609, AC009930.1, EEF1A1P37, LINC02237, SERPINA15P, H2AZP7, AC022360.1, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC055788.1, AC103993.1, Y_RNA, AC064802.1, AC025881.1, CARS1P2.

Autosomal genes at a single copy (total copy number 1): 393. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
